Somatic mutation profile of tumor specimen 0DHBD6 from CCDI case PBBUBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 0.6 years (209 days).
Specimen 0DHBD6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42c4a31c-a61d-4db8-ade6-c41bb5ca0c38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHBCV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e6193f9-7a80-4fcc-899c-e5bd84daca50

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 272/793 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 343/1091 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs371102650; called by muse, mutect2, varscan2
- CACNA1B | c.6173G>A p.R2058H | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs201114958; called by muse, mutect2, varscan2
- MYOG | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 166/378 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54096577; called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 32/1223 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LDOC1 | c.429G>A p.E143= | Silent (SNP) | VAF 93/363 reads (26%) | called by muse, mutect2, varscan2
- MED13 | c.1998A>G p.K666= | Silent (SNP) | VAF 40/1177 reads (3%) | called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 30/748 reads (4%) | called by muse, mutect2
